HCMI case HCM-CSHL-1265-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78f0db28-1e72-4fad-9515-5ff0e0d9ddf7

Demographics
Sex at birth: female; Year of birth: 1949; Vital status: Dead; Cause of death: Cancer Related.

Diagnoses (1)
1. Carcinosarcoma, NOS: ICD-O-3 morphology code: 8980/3; ICD-10 code: C25.1; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,004 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 4 or More; Peripancreatic lymph nodes tested: 27.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -25 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 378 days (1.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 259.

Molecular and laboratory tests
- CA19-9: 85.
- CEA: 27.7 ng/mL; Blood test normal range upper: 4.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 60 kg; Height: 153 cm; BMI: 26.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Sulfonylurea.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Pancreas Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-1265-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-1265-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 4; Percent necrosis: 2; Percent stromal cells: 19; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-1265-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 85; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 47; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-1265-C25-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-CSHL-1265-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
